Somatic mutation profile of tumor specimen MP2PRT-PAPRDN-TMP1-A (aliquot MP2PRT-PAPRDN-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPRDN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,149 days).
Specimen MP2PRT-PAPRDN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a466f9c-1d5c-4dd1-88c5-a69a1ad93091.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPRDN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPRDN-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8338a39b-45e4-44be-a6aa-fa65a1fd5886

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 13, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 113/275 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BEND2 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV66216488; called by muse, mutect2, varscan2
- CTAGE6 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs747558071; called by muse, mutect2
- CTTN | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 93/182 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs900700542; called by muse, mutect2, varscan2
- DCAF8L2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 172/344 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101445717, COSV101445882, COSV70553366; called by muse, mutect2, varscan2
- ERG | c.1108G>A p.D370N (on ENST00000398919 / NM_001243428.1; = p.D346N on NM_004449.4) | Missense Mutation (SNP) | VAF 366/914 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55727362; called by muse, mutect2, varscan2
- HSPG2 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 122/248 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375748367; called by muse, mutect2, varscan2
- OR2T11 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 128/263 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs1235848068; called by muse, mutect2, varscan2
- ROR2 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 157/333 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs374141378; called by muse, mutect2, varscan2
- TAF1L | c.3614G>A p.R1205Q | Missense Mutation (SNP) | VAF 166/331 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs749284231, COSV54256396; called by muse, mutect2, varscan2
- NAV2 | c.937A>G p.N313D (on ENST00000396087 / NM_001244963.2; = p.N290D on NM_145117.5) | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NCKAP5 | c.5611G>T p.A1871S | Missense Mutation (SNP) | VAF 105/236 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TYRP1 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 152/346 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPN1 | c.153C>A p.A51= | Silent (SNP) | VAF 275/515 reads (53%) | called by muse, mutect2, varscan2
